Somatic mutation profile of tumor specimen TCGA-VQ-A8P8-01A (aliquot TCGA-VQ-A8P8-01A-11D-A397-08) from TCGA case TCGA-VQ-A8P8, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 72.4 years (26,443 days).
Specimen TCGA-VQ-A8P8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 340b1e40-f42e-401c-8b66-b994301b6d21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8P8-10A (Blood Derived Normal), aliquot TCGA-VQ-A8P8-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7438381e-893e-4b72-a54f-d6b75bcdc4a8

The open-access MAF lists 91 somatic variants for this specimen: 67 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 58, Silent 24, Nonsense Mutation 6, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PC | c.2723C>T p.T908M | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052032, COSV58992858; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69041792, COSV69042056; called by muse, mutect2, varscan2
- ABCA7 | c.4211A>G p.K1404R | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs1229814368, COSV99565616; called by muse, mutect2, varscan2
- ACACB | c.4511G>A p.R1504Q | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs549887432, COSV58147231; called by muse, mutect2, varscan2
- ADCY8 | c.1468A>C p.I490L | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as COSV99651798; called by muse, mutect2
- AMBRA1 | c.2585T>C p.L862P (on ENST00000458649 / NM_001367468.1; = p.L772P on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100093588; called by muse, mutect2
- ANKRD10 | c.562T>G p.F188V | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV99941101; called by muse, mutect2, varscan2
- ARHGAP33 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.983); catalogued as rs374221923; called by muse, mutect2, varscan2
- ARID1A | c.5326G>T p.E1776* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100251332; called by mutect2, varscan2
- ASTN1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.552); catalogued as COSV56065124; called by muse, mutect2, varscan2
- CCPG1 | c.1817dup p.N606Kfs*12 | Frame Shift Ins (INS) | VAF 12/113 reads (11%) | catalogued as rs1428090013; called by mutect2, pindel, varscan2
- CDC42BPB | c.2233C>T p.R745* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as COSV63477685; called by muse, mutect2
- CFAP100 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV61503442; called by muse, mutect2, varscan2
- CFH | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1300493671, COSV62776836; called by muse, mutect2
- CHST1 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1460339975, COSV57322115; called by muse, mutect2
- CLDN9 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV100172140; called by muse, varscan2
- CNTLN | c.3940G>A p.A1314T | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs772018140, COSV52093696; called by muse, mutect2
- COL24A1 | c.118C>G p.Q40E | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.239); catalogued as COSV100993185; called by muse, mutect2
- CPAMD8 | c.1891G>A p.E631K (on ENST00000651564; = p.E584K on NM_015692.5) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770476590, COSV52232660; called by muse, mutect2, varscan2
- CYP4F12 | c.1290C>A p.N430K | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100215785; called by muse, mutect2, varscan2
- DGKI | c.1987C>T p.Q663* | Nonsense Mutation (SNP) | VAF 14/108 reads (13%) | catalogued as rs1259742633, COSV99933797; called by muse, mutect2, varscan2
- DSEL | c.1472G>C p.G491A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025574, COSV59491378; called by muse, mutect2
- ENG | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.112); catalogued as COSV100785281; called by muse, mutect2
- ERBB3 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403278713, COSV57247278, COSV57260257; called by muse, mutect2
- FAM53C | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.024); catalogued as COSV99524335; called by muse, mutect2
- FAT4 | c.14893G>A p.G4965S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.003); catalogued as COSV100628334; called by muse, mutect2
- FRY | c.6388A>G p.I2130V | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV100969123; called by muse, mutect2, varscan2
- HERC1 | c.7561G>A p.A2521T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs963612854, COSV101496511; called by muse, mutect2, varscan2
- HSD17B7 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99597662; called by muse, mutect2
- IGSF1 | c.1994A>G p.E665G | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV100812044; called by muse, mutect2
- ITPRID2 | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100238158; called by muse, mutect2, varscan2
- KCNB2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.188); catalogued as rs761567231, COSV101578745; called by muse, mutect2, varscan2
- KCNG2 | c.745G>A p.A249T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs780887506, COSV60266517; called by muse, mutect2, varscan2
- KCNH8 | c.1375+1G>A p.X459_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV60465123; called by muse, mutect2
- KIAA1109 | c.6871G>T p.E2291* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV99155258; called by muse, mutect2, varscan2
- LRRK2 | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as rs1204504921, COSV100109932, COSV100110781; called by muse, mutect2
- LRRTM4 | c.1674C>A p.D558E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs138192949, COSV69168586, COSV69187189; called by mutect2, varscan2
- MAGEA8 | c.545T>A p.V182D | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99674537; called by muse, mutect2
- MUC16 | c.7925C>T p.T2642I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101199524; called by muse, mutect2, varscan2
- MYO3B | c.3619G>A p.A1207T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs766640832, COSV58693730; called by muse, mutect2, varscan2
- MYT1L | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.163); catalogued as COSV67721089; called by muse, mutect2, varscan2
- NELFE | c.76-1G>C p.X26_splice | Splice Site (SNP) | VAF 20/128 reads (16%) | catalogued as COSV100952690; called by muse, mutect2, varscan2
- NKX6-2 | c.677A>G p.K226R | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.718); catalogued as COSV100888333; called by muse, mutect2
- NUP214 | c.1299T>G p.S433R | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100845240; called by muse, mutect2
- PCNX3 | c.5084C>T p.T1695M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.132); catalogued as rs371964481; called by muse, mutect2, varscan2
- PLXNA2 | c.4286G>A p.R1429K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100885379; called by muse, mutect2
- POLA1 | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as COSV66884999; called by muse, mutect2, varscan2
- RAB6B | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99557936, COSV99558287; called by muse, mutect2
- RMND5A | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 23/184 reads (13%) | catalogued as COSV99373678; called by muse, mutect2, varscan2
- RTL4 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as COSV100465873; called by muse, mutect2
- SALL1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs140165636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHISAL2A | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101284238; called by muse, mutect2
- SLC22A6 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100842822; called by muse, mutect2
- SLITRK2 | c.1724A>G p.E575G | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100157637; called by muse, mutect2
- SYNGAP1 | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV99538239; called by muse, mutect2
- TMC7 | c.1651C>A p.Q551K | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100432441; called by muse, mutect2
- TNKS1BP1 | c.2252G>C p.G751A | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as COSV100835971; called by muse, mutect2, varscan2
- TNP2 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs759134912, COSV57130040; called by muse, mutect2, varscan2
- TONSL | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as rs764909171, COSV101340219; called by muse, mutect2, varscan2
- TRAV23DV6 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.177); catalogued as rs1428521250; called by muse, mutect2, varscan2
- TRPM8 | c.1454G>A p.R485Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs200772894, COSV61220820, COSV61222025; called by muse, mutect2
- TTN | c.43948A>C p.T14650P (on ENST00000591111; = p.T7226P on NM_003319.4) | Missense Mutation (SNP) | VAF 8/46 reads (17%) | PolyPhen possibly damaging (0.827); catalogued as COSV100607673; called by muse, mutect2, varscan2
- XCR1 | c.996C>A p.F332L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100499348; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1994G>T p.C665F | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99837587; called by muse, mutect2, varscan2
- ZNF382 | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV99497733; called by muse, mutect2, varscan2
- ZNF521 | c.1992G>T p.L664F | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.985); catalogued as COSV100831941; called by muse, mutect2
- ZNF528 | c.1276C>T p.R426* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as rs142519187; called by muse, mutect2, varscan2
- ATMIN | c.1338G>A p.S446= | Silent (SNP) | VAF 10/150 reads (7%) | catalogued as rs371161001; called by muse, mutect2
- BACH2 | c.2199C>T p.L733= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as COSV99998993; called by muse, mutect2
- COL6A2 | c.642C>T p.N214= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs781584161, COSV56003660; called by mutect2, varscan2
- CRACD | c.3570G>A p.A1190= | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs769044029, COSV51723947; called by muse, mutect2, varscan2
- FSCN3 | c.204C>T p.S68= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs1380136517, COSV50000844; called by muse, mutect2, varscan2
- HTR2C | c.274T>C p.L92= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as COSV52220044, COSV99349019; called by muse, mutect2, varscan2
- JMJD1C | c.5259A>G p.R1753= | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as COSV100550435; called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.507C>T p.F169= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV53277870; called by muse, mutect2, varscan2
- MYH13 | c.1902C>T p.S634= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as rs1248483238; called by muse, mutect2
- OR2T1 | c.861C>T p.L287= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV100822297; called by muse, mutect2
- PCDHGB6 | c.1371C>T p.Y457= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs562811168, COSV54034860, COSV99531370; called by muse, mutect2, varscan2
- PLCD4 | c.2199C>T p.H733= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV101346868, COSV68744709; called by muse, mutect2
- POU4F1 | c.1125C>T p.A375= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as COSV101020528; called by muse, mutect2
- POU4F2 | c.570C>T p.G190= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as rs1396766602, COSV99850725; called by muse, mutect2
- PPP1R26 | c.2706C>T p.A902= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as rs372949310; called by muse, mutect2, varscan2
- RAP1GAP | c.1656G>A p.A552= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs961786710, COSV99265162; called by muse, mutect2, varscan2
- RDH11 | c.576C>T p.G192= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs764879646, COSV67282519; called by muse, mutect2, varscan2
- SARDH | c.1107C>T p.P369= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs149815756, COSV64097729; called by mutect2, varscan2
- SLC2A7 | c.66G>A p.T22= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs779161530, COSV68901675; called by mutect2, varscan2
- SLC35F3 | c.225C>T p.C75= (on ENST00000366617 / NM_001300845.1; = p.C144= on NM_173508.4) | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV100784775; called by muse, mutect2, varscan2
- THSD7A | c.3423A>G p.V1141= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs889903567, COSV101439744; called by muse, mutect2, varscan2
- TONSL | c.3597C>T p.N1199= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs374357745, COSV52871206; called by muse, mutect2, varscan2
- TXLNG | c.849C>T p.Y283= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs937333880, COSV101200566; called by muse, mutect2, varscan2
- ZXDA | c.1176G>A p.A392= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100699403; called by muse, mutect2, varscan2
